Gene-level copy-number profile of tumor specimen TCGA-08-0392-01A from TCGA case TCGA-08-0392, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.4 years (22,056 days).
Specimen TCGA-08-0392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.a33c0e1c-3740-4e8c-9eaa-4a124b8a3b74.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-08-0392-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82d2f99b-13dc-4b97-ba56-c23a24ee4cae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 9,816; copy number 2: 45,661; copy number 3: 4,308.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0392-01): tumor purity 0.82, ploidy 1.98, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:161,347,417–162,727,775, 1 gene (within-gene range 0–2): PRKN.
- chr6:162,568,379–165,077,495, 26 genes (within-gene range 0–2): KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1.
- chr9:21,967,752–22,128,103, 7 genes: CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,436. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
